Surgical pathology report (de-identified scan), TCGA case TCGA-42-2582, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-42-2582-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Omentum
- B. Left tube and ovary
- C. Uterus, portion of cervix, right tube and ovary
- D. Appendix
- E. Cul-de-sac tumor
- F. Round ligament bladder peritoneum
- G. Sigmoid tumor
- H. Left pelvic sidewall

CLINICAL NOTES

PRE-OP DIAGNOSIS: Pelvic pain, possible ovarian carcinoma.
POST OP DIAGNOSIS: Same.

FROZEN SECTION DIAGNOSIS

B) Ovary & fallopian tube, salpingectomy & oophorectomy; left:
Carcinoma.

GROSS DESCRIPTION

A. Received fresh labeled "omentum" is a 25.0 x 11.0 x 2.5 cm. portion of rubbery lobulated tan white-gold tissue in keeping with omentum involved by metastasis. Random representative sections are submitted in four blocks. RS4.

B. Received unfixed for frozen section and tissue procurement, labeled "left tube and ovary," is a partially fragmented specimen consisting of ovary and fallopian tube. There is a detached portion of fatty tissue, 2.9 x 1.8 x 0.6 cm. (see block 1). The ovary has a fragmented tumor, portions of which are detached and received separately in the container. A portion of this tumor is submitted for tissue procurement. The detached portion of tumor is 2.7 x 2.3 x 0.8 cm. Portions of this fragment are tan-pink with an irregular surface (see block B2). The ovary with tumor that is attached to the adnexa is 5.5 x 2.6 x 2.3 cm. A portion of the ovary is uninvolved by tumor and shows a hemorrhagic

GROSS DESCRIPTION

cyst with thin focal orange-yellow lining. This portion is 2.5 x 1.7 x 2.0 cm. The portion that is tumor mass is ill-defined due to fragmentation, but approximately 3.0 x 3.0 x 2.2 cm. The external surface of the ovary (capsule), and cyst is irregular, with possible tumor nodules. The ovary shows an apparent breach in surface capsule (block B3-B4). Portion of capsule with possible serosal tumor is submitted in B5-B6. On edge. B7 shows portions of corpus luteal cyst. The attached fallopian tube is edematous and dilated, 7 cm. in length, 1.0 cm. at the isthmus and with fimbriated ends with protruding mass lesion. (B8). The adnexal area shows possible tumor involvement, with representative section submitted in B9-11.

- C. Received fresh labeled "uterus, portion of cervix, right tube and ovary" is a 145 gram, 5.5 cm. (superior to inferior) by 5.5 cm. (cornu to cornu) by 5.0 cm. (anterior to posterior) symmetrical uterine corpus with attached 1.8 cm. portion of superior cervix and right adnexa. The serosa is scabrous tan white-red with apparent adherent tumor along the anterior aspect. Ectocervical mucosa is not present. Endocervical mucosa is mildly trabecular glistening pale tan pink with a scant amount of adherent clear mucous. The triangular, 3.5 x 2.3 cm. uterine cavity is lined by lush tan pink-red endometrium averaging 0.3 cm. The myometrium is

[page 2 of 3]
smooth to mildly trabecular pale tan pink and measures up to 2 cm. in thickness. The right ovary is focally torn, dusky white tan to red purple, measuring 5.0 x 4.3 x 3.4 cm. Tan white tumor is present along the capsular surface. On sectioning, the cut surfaces are glistening to chalky tan white-pink and no residual ovarian stroma is identified. The fimbriated red purple right fallopian tube measures 5.8 cm. in length and ranges from 0.5 to 0.9 cm. in diameter. The lumen is pinpoint in stellate on sectioning. Representative sections are submitted in 12 blocks as labeled. RS12.

GROSS DESCRIPTION

BLOCK SUMMARY: 1 - Serosa; 2 - anterior cervix (distal end inked blue); 3 - posterior cervix (distal end inked orange); 4 - anterior endomyometrium; 5 - posterior endomyometrium; 6 - 11 - right ovary; 12 - right tube.

D. Received fresh labeled "appendix" is an 8 cm. appendix ranging from 0.4 cm. in diameter proximally up to 1.8 cm. at the distal tip with a copious amount of associated dusky tan gold-purple mesoappendix. Diffused tan white fibrinopurulent exudate is noted. On sectioning the distal tip contains a calcified fecolith. The appendiceal lumen is pinpoint surrounded by unremarkable tan pink mucosa and the wall averages 0.2 cm. in thickness. Several foci of aberrant tan white tumor are noted throughout the distal end of the specimen within the mesoappendix (see blocks 3 and 4). Representative sections are submitted in four blocks as labeled. RS4.

BLOCK SUMMARY: 1 - Proximal margin and one half of bisected distal tip; 2 - remainder of bisected distal tip; 3 and 4 - representative from remainder of specimen.

E. Received fresh labeled "cul-de-sac tumor" is an irregular, 1.7 x 1.0 x 0.7 cm. fragment of rubbery dusky tan white-purple tissue which is entirely submitted in one block. AS1.

F. Received fresh labeled "round ligament bladder peritoneum" is an irregular, 6.5 x 5.3 x 1.8 cm. fragment of rubbery dusky tan white-gold tissue in keeping with peritoneum and fat. Random representative sections are submitted in four blocks. RS4.

G. Received fresh labeled "sigmoid tumor" is a 2.1 x 1.9 x 0.6 cm. of aggregate of fragmented rubbery dusky tan-white gray tissue which is entirely submitted in one block. AS1.

GROSS DESCRIPTION

H. Received fresh labeled "left pelvic sidewall" is an irregular, 5.2 x 2.6 x 1.8 cm. fragmented portion of rubbery tan white-gold tissue. Representative sections are submitted in two blocks. RS2.

[page 3 of 3]
MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma, Serous.
Histologic grade: III
Primary tumor TNM (FIGO): pT3c - Carcinoma involves both ovaries and fallopian tubes, the appendix, the omentum (metastatic foci greater than 2.0 cm), the uterine serosa, the cul-de-sac and sidewall, and the surfaces of the bladder and bowel.
Angiolymphatic invasion: Present.
Regional lymph nodes: Not assessed (pNx).
Peritoneal fluid: Positive -
Distant metastasis: Positive pleural fluid (pM1) - see
Other: uterus with adenomyosis.

5, 4, 3x5, 2, 14

DIAGNOSIS

- A. Omentum, omentectomy:
Adenocarcinoma, multiple nodules, size > 2.0 cm
- B. Ovary and fallopian tube, left, salpingo-oophorectomy:
Poorly-differentiated adenocarcinoma, involving ovary (ruptured) and fallopian tube.
See microscopic description.
- C. Uterus, portion of cervix, right ovary and fallopian tube, hysterectomy, supracervical, and right salpingo-oophorectomy:

DIAGNOSIS

- Adenocarcinoma, involving the uterine serosa in multiple areas.
Carcinoma involves right ovary and fallopian tube.
Endometrium proliferative and uninvolved by carcinoma.
- D. Appendix, appendectomy:
Periappendiceal adenocarcinoma.
Resection margin free of carcinoma.
- E. Soft tissue, cul-de-sac, biopsy:
Adenocarcinoma.
- F. Soft tissue, round ligament/bladder peritoneum, biopsy:
Adenocarcinoma.
- G. Soft tissue, "sigmoid tumor", biopsy:
Adenocarcinoma.
- H. Soft tissue, left pelvic sidewall, biopsy:
Adenocarcinoma.

(Electronic Signature)

Source: NCI Genomic Data Commons file 54dedb6b-a63e-4d06-8bf3-6e25d4cf21be (TCGA-42-2582.04201F3C-F4FF-4F85-8C14-F1D754DAFDD6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).